Somatic mutation profile of tumor specimen CDDP-ABJI-TTP1-A (aliquot CDDP-ABJI-TTP1-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABJI, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 73 years.
Specimen CDDP-ABJI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3461c36c-5720-4c6b-b533-1f813a5f38fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABJI-NB1-A (Blood Derived Normal), aliquot CDDP-ABJI-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/788b80e7-9956-4a87-aae6-52d245628143

The open-access MAF lists 58 somatic variants for this specimen: 34 protein-altering or splice-affecting, 15 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 15, Intron 9, Nonsense Mutation 4, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 141/429 reads (33%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- GUCY1A1 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 20/227 reads (9%) | catalogued as rs373182378, COSV99638344; ClinVar: pathogenic; called by muse, mutect2
- ASTL | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs139129570, COSV60905222; called by muse, mutect2, varscan2
- DCAF12L2 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 104/316 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100758880; called by muse, mutect2, varscan2
- FRMPD4 | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as rs370344979, COSV66213661; called by muse, mutect2, varscan2
- SCN10A | c.2746C>T p.R916W | Missense Mutation (SNP) | VAF 81/333 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370208223; called by muse, mutect2, varscan2
- SORCS3 | c.2009+1G>A p.X670_splice | Splice Site (SNP) | VAF 8/60 reads (13%) | catalogued as rs769407927, COSV63793190; called by muse, mutect2, varscan2
- SPINK5 | c.2759G>A p.R920Q | Missense Mutation (SNP) | VAF 93/513 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.234); catalogued as rs371134163, COSV99806409; called by muse, mutect2, varscan2
- SPRY2 | c.644A>G p.Y215C | Missense Mutation (SNP) | VAF 90/343 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755298994; called by muse, mutect2, varscan2
- TMEM132C | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1031403892, COSV59431751; called by muse, mutect2, varscan2
- USP15 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.445); catalogued as COSV54790718; called by muse, mutect2
- ZNF592 | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 154/657 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777199337; called by muse, mutect2, varscan2
- ZNF839 | c.1117C>T p.Q373* (on ENST00000558850 / NM_001267827.1; = p.Q489* on NM_018335.5) | Nonsense Mutation (SNP) | VAF 71/334 reads (21%) | catalogued as rs749707926; called by muse, mutect2, varscan2
- CCDC71L | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CDC42BPB | c.1046A>T p.N349I | Missense Mutation (SNP) | VAF 80/304 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- CNTN1 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MAGEB6B | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 12/323 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAK | c.1127T>C p.V376A | Missense Mutation (SNP) | VAF 66/271 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTIF3 | c.494C>G p.S165* | Nonsense Mutation (SNP) | VAF 50/142 reads (35%) | called by muse, varscan2
- NBEA | c.858C>A p.S286R | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NR2F2 | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 107/520 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSTF1 | c.264G>C p.W88C | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDIA3 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PEAR1 | c.811A>T p.N271Y | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PGBD5 | c.412C>T p.R138C (on ENST00000525115; = p.R207C on NM_001258311.2) | Missense Mutation (SNP) | VAF 67/363 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHIP | c.4078C>G p.P1360A | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PLEKHM3 | c.1102C>T p.L368F | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKAG3 | c.479G>A p.C160Y | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB20 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2
- SMARCA4 | c.3685A>T p.I1229F | Missense Mutation (SNP) | VAF 142/532 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- SUCO | c.97T>G p.S33A | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- USP16 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2, varscan2
- WDR81 | c.5101T>G p.F1701V (on ENST00000409644 / NM_001163809.2; = p.F650V on NM_152348.4) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF674 | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 157/736 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- BNIP5 | c.357C>A p.A119= | Silent (SNP) | VAF 39/411 reads (9%) | called by muse, mutect2
- CYBB | c.1290C>T p.N430= | Silent (SNP) | VAF 33/228 reads (14%) | catalogued as rs1031833103; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH1 | c.10734G>A p.S3578= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as rs754326893, COSV70226688; called by muse, mutect2, varscan2
- GALNT9 | c.87C>G p.R29= | Silent (SNP) | VAF 29/143 reads (20%) | called by muse, mutect2, varscan2
- GRIN1 | c.1224C>T p.F408= | Silent (SNP) | VAF 88/302 reads (29%) | catalogued as rs772147719, COSV59294411; called by muse, mutect2, varscan2
- HMGXB4 | c.1131A>G p.P377= | Silent (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
- NUTM2A | c.2352G>A p.S784= | Silent (SNP) | VAF 298/1007 reads (30%) | catalogued as rs1390723659; called by muse, mutect2, varscan2
- PADI4 | c.561G>A p.T187= | Silent (SNP) | VAF 55/324 reads (17%) | catalogued as rs775568062, COSV64924876; called by muse, mutect2, varscan2
- POLR3E | c.246C>T p.D82= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as rs764860863, COSV55398871; called by muse, mutect2, varscan2
- PRRG1 | c.615C>G p.A205= | Silent (SNP) | VAF 16/80 reads (20%) | called by muse, varscan2
- PTK7 | c.1698C>T p.G566= | Silent (SNP) | VAF 60/157 reads (38%) | called by muse, mutect2, varscan2
- STMN1 | c.117T>A p.P39= | Silent (SNP) | VAF 49/266 reads (18%) | called by muse, mutect2, varscan2
- SUMO4 | c.225G>A p.Q75= | Silent (SNP) | VAF 48/169 reads (28%) | called by muse, mutect2, varscan2
- TLR6 | c.153G>A p.P51= | Silent (SNP) | VAF 58/231 reads (25%) | catalogued as rs554325518; called by muse, mutect2, varscan2
- TTN | c.24357T>C p.N8119= (on ENST00000591111; = p.N7192= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- BUB3 | c.971+18G>T | Intron (SNP) | VAF 20/80 reads (25%) | called by mutect2, varscan2
- C8orf44-SGK3 | c.-481-1821A>T | Intron (SNP) | VAF 16/66 reads (24%) | called by muse, varscan2
- PAQR6 | c.760+33G>A | Intron (SNP) | VAF 32/119 reads (27%) | called by muse, mutect2, varscan2
- PRRC1 | c.1128+107_1128+108insC | Intron (INS) | VAF 39/174 reads (22%) | called by mutect2, pindel*
- SLC35B1 | c.216-327A>G | Intron (SNP) | VAF 15/90 reads (17%) | catalogued as rs753771286; called by muse, mutect2, varscan2
- SLX1B | c.711-30G>C | Intron (SNP) | VAF 44/398 reads (11%) | catalogued as rs763828162; called by mutect2, varscan2
- TMEM175 | c.842+475C>G | Intron (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
- TRIM61 | c.526-2267T>A | Intron (SNP) | VAF 122/428 reads (29%) | called by muse, mutect2, varscan2
- UBR2 | c.1281+75A>G | Intron (SNP) | VAF 10/253 reads (4%) | catalogued as rs1411541517, COSV65752876; called by muse, mutect2
